Surgical pathology report (de-identified scan), TCGA case TCGA-XF-A9T3, project TCGA-BLCA (Bladder Urothelial Carcinoma), tissue source site University of Southern California, specimen TCGA-XF-A9T3-01A (Primary Tumor).

[page 1 of 7]
Collected:
Ordered by:

DIAGNOSIS:

ANTERIOR PELVIC EXENTERATION, STUDER POUCH TO URETHRA, PELVIC LYMPHADENECTOMY AND G-TUBE PLACEMENT:

RIGHT DISTAL URETER (AFS):

FROZEN SECTION DIAGNOSIS:

- NO HIGH GRADE ATYPIA OR TUMOR IDENTIFIED

FINAL DIAGNOSIS:

- BENIGN URETER

- NO UROTHELIAL DYSPLASIA OR MALIGNANCY IDENTIFIED

LEFT DISTAL URETER (BFS):

FROZEN SECTION DIAGNOSIS:

- NO HIGH GRADE ATYPIA OR TUMOR IDENTIFIED

FINAL DIAGNOSIS:

- BENIGN URETER

- NO UROTHELIAL DYSPLASIA OR MALIGNANCY IDENTIFIED

LEFT PARA AORTIC LYMPH NODES (CFS):

FROZEN SECTION DIAGNOSIS:

- BENIGN

FINAL DIAGNOSIS:

- NO MALIGNANCY IDENTIFIED IN SEVEN LYMPH NODES EXAMINED (0/7)

APICAL URETHRAL MARGIN (DFS):

FROZEN SECTION DIAGNOSIS:

- NO HIGH GRADE ATYPIA OR TUMOR IDENTIFIED

FINAL DIAGNOSIS:

- BENIGN URETHRAL AND PERIURETHRAL TISSUE

- NO UROTHELIAL DYSPLASIA OR MALIGNANCY IDENTIFIED

BLADDER, UTERUS, BILATERAL OVARIES AND TUBES AND CERVIX (E):

INTRAOPERATIVE GROSS DIAGNOSIS:

- TUMOR EXTENDING THROUGH WALL WITH CLEAR MARGINS

FINAL DIAGNOSIS:

BLADDER:

- INVASIVE POORLY DIFFERENTIATED UROTHELIAL CARCINOMA (3.5 X 3 X 1.8 CM), GRADES 3 & 4/4, EXTENDING GROSSLY AND MICROSCOPICALLY THROUGH MUSCULARIS PROPRIA INTO PERIVESICAL SOFT TISSUE OF TRIGONE, LEFT LATERAL WALL, AND LEFT URETEROVESICAL JUNCTION
- LYMPHOVASCULAR INVASION IDENTIFIED
- FOCI OF CYSTITIS GLANDULARIS ET CYSTICA AND ASSOCIATED MILD TO MODERATE UROTHELIAL DYSPLASIA
- NO HIGH GRADE DYSPLASIA OR UROTHELIAL CARCINOMA IN SITU (FLAT LESION) IDENTIFIED
- RESECTION MARGINS, FREE OF UROTHELIAL DYSPLASIA AND MALIGNANCY

UTERUS:

- CERVIX, CHRONIC CERVICITIS AND SQUAMOUS METAPLASIA
- VAGINAL CUFF, MILD CHRONIC INFLAMMATION
- ENDOMETRIUM, INACTIVE
- MYOMETRIUM, SEROSA, AND BILATERAL FALLOPIAN TUBES SHOWING NO SIGNIFICANT LESION
- BILATERAL OVARIES, BENIGN PHYSIOLOGIC CHANGES
- NO ATYPIA, DYSPLASIA OR MALIGNANCY IDENTIFIED

RIGHT PARA CAVAL LYMPH NODES (F):

- NO MALIGNANCY IDENTIFIED IN TWO LYMPH NODES EXAMINED (0/2)

ICD O-3
Carcinoma, urothelial NOS
812013
Site: Bladder NOS
C67.9
Jt 3/26/14

[page 2 of 7]
Collected:

Ordered by:

Location:

LEFT COMMON ILIAC LYMPH NODES (G):

- NO MALIGNANCY IDENTIFIED IN SEVEN LYMPH NODES EXAMINED (0/7)

RIGHT COMMON ILIAC LYMPH NODES (H):

- NO MALIGNANCY IDENTIFIED IN THREE LYMPH NODES EXAMINED (0/3)

RIGHT EXTERNAL ILIAC LYMPH NODES (I):

- NO MALIGNANCY IDENTIFIED IN FIVE LYMPH NODES EXAMINED (0/5)

RIGHT LYMPH NODE OF CLOQUET (J):

- NO MALIGNANCY IDENTIFIED IN ONE LYMPH NODES EXAMINED (0/1)

RIGHT OBTURATOR/HYPOGASTRIC LYMPH NODE (K):

- NO MALIGNANCY IDENTIFIED IN SIX LYMPH NODES EXAMINED (0/6)

LEFT EXTERNAL ILIAC LYMPH NODES (L):

- METASTATIC CARCINOMA IDENTIFIED IN ONE OF FOUR LYMPH NODES EXAMINED (1/4)

LEFT LYMPH NODE OF CLOQUET (M):

- BENIGN MATURE FIBROADIPOSE TISSUE
- NO LYMPHOID TISSUE OR MALIGNANCY IDENTIFIED (0/0) [ENTIRELY SUBMITTED]

LEFT OBTURATOR/HYPOGASTRIC LYMPH NODES (N):

- NO MALIGNANCY IDENTIFIED IN EIGHT LYMPH NODES EXAMINED (0/8)

RIGHT PELVIC LYMPH NODES (O):

- BENIGN MATURE FIBROADIPOSE TISSUE
- NO LYMPHOID TISSUE OR MALIGNANCY IDENTIFIED (0/0) [ENTIRELY SUBMITTED]

RIGHT PRE SCIATIC LYMPH NODES (P):

- NO MALIGNANCY IDENTIFIED IN THREE LYMPH NODES EXAMINED (0/3)

PRE SACRAL LYMPH NODES (Q):

- METASTATIC CARCINOMA IDENTIFIED IN ONE OF FOUR LYMPH NODES EXAMINED (1/4)

REMOVED LEFT URETERAL STENT (R):

- MEDICAL DEVICE CONSISTENT WITH URETERAL STENT (GROSS ONLY)

LEFT PRE SCIATIC LYMPH NODES (S):

- NO MALIGNANCY IDENTIFIED IN TWO LYMPH NODES EXAMINED (0/2)

LEFT PROXIMAL URETER (T):

- BENIGN URETER
- NO UROTHELIAL DYSPLASIA OR MALIGNANCY IDENTIFIED

RIGHT PROXIMAL URETER (U):

- BENIGN URETER EXHIBITING URETERITIS GLANDULARIS
- NO UROTHELIAL DYSPLASIA OR MALIGNANCY IDENTIFIED

LYMPH NODE SUMMARY: METASTATIC CARCINOMA IDENTIFIED IN TOTAL OF TWO OF 52
LYMPH NODES EXAMINED (2/52),

LARGEST METASTATIC

DEPOSIT 5 MM WITH EXTRANODAL

EXTENSION

PATHOLOGIC TNM STAGE: pT3bN2MX

[page 3 of 7]
Collected:

Ordered by:

Location:

Electronically signed by

Verified:

COMMENT:

Representative sections of invasive carcinoma are submitted for p53 assay by immunohistology, results of which will be issued in an addendum.

SPECIMEN SOURCE:

AFS: "Rt. distal ureter - f/s"
BFS: "Lt. distal ureter - f/s"
CFS: "Lt. para aortic LN- f/s"
DFS: "Apical urethral margin-f/s"
E: "Bladder, uterus, bil. ovaries and tubes and cervix"
F: "Rt. para caval LN"
G: "Lt. common iliac LN"
H: "Rt. common iliac LN"
I: "Rt. external iliac LN"
J: "Rt. LN of Cloquet"
K: "Rt. obturator/hypogastric LN"
L: "Lt. external iliac LN"
M: "Lt. LN of Cloquet"
N: "Lt. obturator/hypogastric LN"
O: "Rt. pelvic LN"
P: "Rt. pre sciatic LN"
Q: "Pre sacral LN"
R: "Removed Lt. ureteral stent"
S: "Lt. pre sciatic LN"
T: "Lt. proximal ureter"
U: "Rt. proximal ureter"

CLINICAL INFORMATION:

Pre-Op Dx: Bladder cancer

Post-Op Dx: Same as pre-op

GROSS EXAMINATION:

A: The specimen is received fresh from the O.R. and labeled "Rt. distal ureter - f/s". It consists of a segment of gray-pink soft tubular tissue measuring 0.4 cm in diameter and 0.4 cm in length. Entirely submitted for frozen section diagnosis and resubmitted for permanent processing in cassette AFS.

B: The specimen is received fresh from the O.R. and labeled "Lt. distal ureter - f/s". It consists of a segment of soft gray-pink tubular tissue measuring 0.5 cm in diameter and 0.5 cm in length. Entirely submitted for frozen diagnosis and resubmitted for permanent processing in cassette BFS.

C: The specimen is received fresh from the O.R. and labeled "Lt. para aortic LN- f/s". It consists of a piece of fibrofatty tissue measuring 3.5 x 1.5 x 0.8 cm which contains five lymph nodes measuring up to 0.5 cm in greatest dimension. Entirely submitted for frozen section diagnosis and resubmitted for permanent processing in cassette CFS.

D: The specimen is received fresh from the O.R. and labeled "Apical urethral margin-f/s". It consists of a piece of soft pink-gray tissue measuring 1.4 x 0.3 x 0.2 cm. Entirely submitted for frozen section diagnosis and resubmitted for permanent processing in cassette DFS.

E: The specimen is received fresh from the O.R. and labeled "Bladder, uterus, bil.

[page 4 of 7]
Collected

Ordered by

Location

ovaries and tubes and cervix". It consists of an anterior pelvic exenteration specimen. Overall, the specimen measures 37 x 16 x 4.5 cm and on the posterior surface has an attached smooth, glistening, mobile, pink-yellow peritoneum measuring 37 x 16 by less than 0.1 cm. The peritoneum does not appear to be involved by tumor. The specimen consists of a bladder (5 x 5 x 2.5 cm), attached globoid uterus (7 x 5 x 1.8 cm), attached bilateral fallopian tubes (right 10 cm in length and 0.4 cm in diameter, left 11 cm in length and 0.4 cm in diameter), and attached bilateral ovaries (right 2.2 x 1.3 x 0.8 cm, left 3.4 x 1 x 0.8 cm). The uterus and bladder are attached but freely mobile with regard to one another. The specimen surgical resection margins are entirely inked black. The bladder is opened along the anterior wall, revealing a pliable uninvolved wall thickness of 1 cm. The right and left ureterovesical junctions are identified and are probe patent. Both ureters are opened. The right attached ureter measures 5.5 cm in length and 0.6 cm in circumference with normal appearing mucosa. The left attached ureter measures 4.5 cm in length and 0.7 cm circumference. Involving the left ureterovesical junction, left lateral wall, and left portions of the posterior wall and trigone is an ulcerated, exophytic, firm, gray-yellow, ill-defined tumor which measures 3.5 x 3 x 1.8 cm. Upon sectioning through the tumor, it extends through the bladder wall and into the perivesical fat but does not involve the inked black resection margin or the peritoneum. The tumor extends to a depth of 1.8 cm and is 0.2 cm from the inked margin and the peritoneum. Cut surfaces of the tumor are solid, firm, homogeneous, and white. The remainder of the bladder and ureteral mucosae are gray and wrinkled. No lymph nodes are grossly palpated in the perivesical fat. The specimen is returned to the OR at the surgeon's request for gross consultation, at which time he is informed that tumor extends grossly through the bladder wall with clear resection margins. The bladder and ureteral mucosae are then fixed in BS fixative for one hour and the specimen is subsequently entirely fixed in formalin for a prolonged period prior to taking sections for permanent processing. The serosa of the uterus is tan-pink, smooth and dull. The fallopian tubes and ovaries are grossly unremarkable. Upon sectioning through the ovaries, the cut sections are white to yellow, solid, firm, and grossly unremarkable. The ectocervix is covered by a shiny, pink-white mucosa. The ectocervix measures 3 x 2 cm and has a flattened os measuring 1.3 x 0.1 cm. Surrounding the ectocervix is a rim of wrinkled, gray-pink vaginal mucosa measuring 0.3 cm wide that appears grossly unremarkable. The uterus is bivalved revealing an endocervical canal measuring 2.5 cm in length that is lined by a smooth tan mucosa. The endometrial cavity measures 2.5 x 1.6 x 0.5 cm and is lined by a thin, soft, tan, uniform endometrium 0.1 cm thick. The myometrium averages 1 cm in thickness and shows no masses or gross abnormalities. Representative sections are submitted in 20 cassettes.

F: The specimen is received in formalin and labeled "Rt. para caval LN". It consists of multiple fragments of fibrofatty and tan-pink lymphoid tissue measuring 2 x 0.8 x 0.3 cm in aggregate. Entirely submitted in one cassette.

G: The specimen is received in formalin and labeled "Lt. common iliac LN". It consists of multiple fragments of fibrofatty and tan-pink lymphoid tissue measuring 4 x 2 x 0.5 cm in aggregate. Entirely submitted in four cassettes.

H: The specimen is received in formalin and labeled "Rt. common iliac LN". It consists of fibrofatty and lymphoid tissue measuring 6.2 x 2 x 0.4 cm. Entirely submitted in three cassettes.

I: The specimen is received in formalin and labeled "Rt. external iliac LN". It consists of a piece of fibrofatty and lymphoid tissue measuring 9 x 2.5 x 0.8 cm in aggregate. Entirely submitted in seven cassettes.

J: The specimen is received in formalin and labeled "Rt. LN of Cloquet". It consists of a tan-pink lymph node measuring 0.4 x 0.2 x 0.2 cm with attached fat measuring 1 x 0.5 x 0.1 cm. Entirely submitted in one cassette.

[page 5 of 7]
Collected:

Ordered by:

Location:

K: The specimen is received in formalin and labeled "Rt. obturator/hypogastric LN". It consists of fragments of fibrofatty and lymphoid tissue measuring 5.5 x 2.5 x 0.5 cm in aggregate. Entirely submitted in four cassettes.

L: The specimen is received in formalin and labeled "Lt. external iliac LN". It consists of multiple fragments of fibrofatty and lymphoid tissue measuring 4 x 2 x 0.4 cm in aggregate. Entirely submitted in three cassettes.

M: The specimen is received in formalin and labeled "Lt. LN of Cloquet". It consists of fragments of fibrofatty tissue measuring 0.4 x 0.4 x 0.1 cm in aggregate. Entirely submitted in one cassette.

N: The specimen is received in formalin and labeled "Lt. obturator/hypogastric LN". It consists of multiple fragments of fibrofatty and tan-pink lymphoid tissue measuring 5 x 3 x 0.8 cm in aggregate. Entirely submitted in five cassettes.

O: The specimen is received in formalin and labeled "Rt. pelvic LN". It consists of fragments of fibrofatty tissue measuring 2.2 x 2 x 0.4 cm in aggregate. Entirely submitted in one cassette.

P: The specimen is received in formalin and labeled "Rt. pre sciatic LN". It consists of multiple fragments of fibrofatty tissue measuring 2 x 1.5 x 0.3 cm in aggregate. Entirely submitted in one cassette.

Q: The specimen is received in formalin and labeled "Pre sacral LN". It consists of a segment of fibrofatty and lymphoid tissue measuring 4 x 1.5 x 0.5 cm. Entirely submitted in two cassettes.

R: The specimen is received fresh in a plastic bag and labeled "Removed Lt. ureteral stent". It consists of a blue plastic catheter which measures 37 cm in length and 0.2 cm in diameter with a 0.1 cm in diameter lumen. The specimen is perforated with tiny holes arranged in a spiral pattern down the length of the catheter. There is no associated soft tissue. Gross description only.

S: The specimen is received in formalin and labeled "Lt. pre sciatic LN". It consists of multiple fragments of fibrofatty and lymphoid tissue measuring 2 x 2 x 0.3 cm in aggregate. Entirely submitted in two cassettes.

T: The specimen is received in formalin and labeled "Lt. proximal ureter". It consists of a segment of gray-pink soft tubular tissue measuring 2 cm in length and 0.4 cm in diameter with attached soft fatty tissue. There is a staple located 0.6 cm from one end. The margin opposite the stapled end is considered the true proximal margin. Serially sectioned and entirely submitted in two cassettes.

U: The specimen is received in formalin and labeled "Rt. proximal ureter". It consists of a segment of gray-pink soft tubular tissue measuring 0.8 cm in length and 0.3 cm in diameter. There are two staples equally spaced along the tubule. The specimen is serially sectioned and entirely submitted in one cassette.

SECTIONS:

AFS: frozen section, right distal ureter
BFS: frozen section, left distal ureter
CFS: frozen section, left para-aortic lymph node
DFS: frozen section, apical urethral margin
E1: bladder, uterus, bilateral ovaries and tubes and cervix; anterior wall of bladder
E2: dome of bladder
E3: posterior wall of bladder
E4: right lateral wall of bladder

[page 6 of 7]
Collected

Ordered by

Location

E5-9: left lateral wall of bladder and tumor
E10: trigone
E11: right ureterovesical junction
E12,13: left ureterovesical junction
E14: base and neck of bladder with edge (inked blue) where DFS removed
E15: anterior vaginal margin and anterior cervix
E16: posterior vaginal margin and posterior cervix
E17: anterior endomyometrium and serosa
E18: posterior endomyometrium and serosa
E19: right fallopian tube and ovary
E20: left fallopian tube and ovary
F: right paracaval lymph nodes; all embedded, with one lymph node inked black and bisected
G1: left common iliac lymph nodes; one lymph node, bisected
G2: two lymph nodes, bisected, one inked black
G3: remaining lymphoid tissue
G4: remaining tissue
H1: right common iliac lymph nodes; one lymph node, serially sectioned
H2: remaining lymphoid tissue
H3: remaining tissue
I1,2: right external iliac lymph nodes; one matted lymph node, serially sectioned
I3-6: each cassette contains one lymph node, bisected
I7: remaining tissue
J: right lymph node of Cloquet - all embedded
K1,2: right obturator/hypogastric lymph nodes; one lymph node, bisected
K3: remaining lymphoid tissue
K4: remaining tissue
L1: left external iliac lymph nodes; one lymph node, bisected
L2: remaining lymphoid tissue
L3: remaining tissue
M: left lymph node of Cloquet - all embedded
N1,2: left obturator/hypogastric lymph nodes; one lymph node, bisected
N3: one lymph node, bisected
N4: remaining lymphoid tissue
N5: remaining tissue
O: right pelvic lymph nodes
P: right presciatic lymph nodes
Q1: presacral lymph nodes; one lymph node, bisected
Q2: remaining tissue
S1: left presciatic lymph nodes; one lymph node, bisected
S2: remaining tissue
T1: left proximal ureter; proximal margin
T2: remainder of specimen
U: right proximal ureter - all embedded

INTRAOPERATIVE FROZEN CONSULTATION:

AFS: Right distal ureter:
- no high grade atypia or tumor identified

BFS: Left distal ureter:
- no high grade atypia or tumor identified

CFS: Left para-aortic lymph node:
- benign

[page 7 of 7]
Collected:

Ordered by:

Location:

DFS: Apical urethral margin:

- no high grade atypia or tumor identified

INTRAOPERATIVE GROSS CONSULTATION

Bladder, uterus, bilateral tubes, ovaries and cervix (A):

- tumor extending through wall with clear margins

MICROSCOPIC EXAMINATION:

A-D: See final microscopic-diagnosis.

E: Sections of the bladder show an invasive poorly differentiated urothelial carcinoma, grades 3 & 4/4, that involves the left lateral wall (E5-9), trigone (E10), left ureteral vesical junction (E12,13) and base of bladder (E14). The tumor extends through the muscularis propria and into the perivesical fat but does not involve the peritoneum or the inked margins. The closest inked resection margin is 0.2 cm from tumor (E5). Lymphovascular invasion is noted (E8,10,13). Multiple foci of mild to moderate urothelial dysplasia are identified in the left lateral wall (E6, 8), trigone (E10), right UVJ (E11), and left UVJ (E12, 13), but no urothelial carcinoma in situ (flat lesion).

F-U: See final microscopic-diagnosis.

Source: NCI Genomic Data Commons file 1b651787-e2e7-4373-b903-2cdb1ddad4b8 (TCGA-XF-A9T3.F782DE7F-4DE3-476D-BDF6-549CD871EE9C.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).